Surgical pathology report (de-identified scan), TCGA case TCGA-KP-A3W4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site British Columbia Cancer Agency, specimen TCGA-KP-A3W4-01A (Primary Tumor).

[page 1 of 3]
Anatomical Pathology

Surgical Pathology Consultation Report

Case Number:

Patient's
Name:

Collect Date:

MRN:

Receive Date:

PHN:

Date Reported:

DOB/Gender:

Ordering

Physician:

Final Diagnosis:

A. Left pelvic lymph nodes: Nine negative lymph nodes.

B. Uterus (with cervix), tubes and ovaries:

1. High-grade serous carcinoma of endometrium.
2. Deep myometrial invasion to within 3 mm of the serosa.
3. Lymphatic and venous invasion identified.
4. Implant of high-grade serous carcinoma on serosa of left ovary.
5. Detached fragments of serous carcinoma in lumen of right fallopian tube.
6. Myometrial leiomyomas.
7. Noncarcinomatous endometrium: atrophic.
8. Cervix, right ovary, and left fallopian tube negative for tumour.

C. Right pelvic lymph nodes: Approximately 10 negative lymph nodes.

D. Peritoneal washings: Positive for high-grade serous carcinoma.

Electronically signed by

Clinical History as Provided by Submitting Physician:
Corresponding cytology

1C003

Carcinoma, serous, NOS

8441/3

Site:

endometrium

C54.1

4-25-12
RD

Specimens Received:

A: left pelvic lymph node

[page 2 of 3]
B: uterus, ovaries, tubes & cervix

C: right pelvic lymph node

Gross Description:

Received are three containers, each labelled with the patient's name, and demographics.

Container A is labelled LEFT PELVIC LYMPH NODES and consists of multiple fatty tissue fragments aggregating to 3 cm in maximum dimension. Nine lymph nodes are identified ranging from 0.3 to 2.2 cm in maximum dimension. The specimen is submitted as follows:

A1 -single sectioned lymph node

A2 -two lymph nodes, bisected

A3 -two lymph nodes, bisected

A4 -two lymph nodes

A5 -two lymph nodes

A6 -the remaining tissue

Container B is labelled UTERUS, FALLOPIAN TUBES, OVARIES AND CERVIX and consists of a total hysterectomy specimen weighing 175 g. The uterine corpus measures 5.5 x 6.5 x 5.5 cm, and the cervix measures 2.8 x 2.5 cm. The right fallopian tube measures 5 x 0.3 cm diameter and the right ovary measures 2.7 x 1.1 x 0.7 cm. The left fallopian tube measures 6 x 0.3 cm diameter and the left ovary measures 2.3 x 1 x 0.7 cm. The serosal surface is smooth and the uterine corpus is globular and shows multiple subserosal and intramural leiomyomas. The leiomyomas range from 0.1 to 3.2 cm diameter. The uterine cavity is occupied by a fungating, soft, friable tumour that arises from the fundus and extends through the anterior and posterior uterine wall. The tumour is 1.2 cm from the anterior lower uterine segment and is 1.5 cm from the posterior lower uterine segment. The cervical mucosa is grossly unremarkable. The tumour invades into the outer half of the myometrium and is approximately 0.3 cm from the serosal surface. Both fallopian tubes and ovaries are grossly unremarkable. Sections are submitted as follows:

B1 -anterior cervix

B2 -posterior cervix

B3 -anterior lower uterine segment

B4 -posterior lower uterine segment

B5-B7 -representative section from the anterior uterine wall

B8-B14 -representative section from the posterior uterine wall

B15 -cul-de-sac

B16-B18 -right fallopian tube, submitted in toto

B19 -right ovary

B20-B22 -left fallopian tube, submitted in toto

B23 -representative section from the left ovary

Container C is labelled RIGHT PELVIC LYMPH NODE and consists of multiple fatty

[page 3 of 3]
tissue fragments aggregating to 4 cm in maximum dimension. Six lymph nodes are identified ranging from 0.3 to 2.3 cm in maximum dimension. Sections are submitted as follows:

- C1 -a single bisected lymph node
- C2 -two lymph nodes, one is inked with black ink and bisected
- C3,C4 -a single sectioned lymph node
- C5 -two lymph nodes, one is inked with black ink
- C6,C7 -the remaining fatty tissue

Copies to:

Source: NCI Genomic Data Commons file 0b1b8c44-ffca-4ace-82a6-dc3e33f67fd5 (TCGA-KP-A3W4.5B8C1B60-7046-4A3A-9D65-ECCB91BF9847.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).